Gene-level copy-number profile of tumor specimen TCGA-BR-8680-01A from TCGA case TCGA-BR-8680, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 45.5 years (16,637 days).
Specimen TCGA-BR-8680-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.20394bc7-7306-48a9-b459-163b909d67c9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8680-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9481403f-159c-4391-bdf2-23e0d04353a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,741; copy number 2: 54,191; copy number 3: 2,865; copy number 4: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8680-01A-11D-2390-01): tumor purity 0.68, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,795. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
